Gene-level copy-number profile of tumor specimen TARGET-51-PALFYG-01A from TARGET case TARGET-51-PALFYG, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.7 years (256 days).
Specimen TARGET-51-PALFYG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.6a783385-0c24-520c-b400-8b31b85e463e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PALFYG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate.
https://portal.gdc.cancer.gov/files/2a7012a5-0a01-4bad-8870-4117377ea074

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,395; copy number 1: 935; copy number 2: 56,745; copy number 3: 18; copy number 4: 2; copy number 5: 1; copy number 7: 6; copy number 8: 119; copy number 9: 11.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:173,431,349–173,431,812, 1 gene: JPT1P1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr19:47,801,243–47,992,170, 6 genes: TPRX1, CRX, TPRX2P, LINC01595, SULT2A1, BSPH1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 137 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:108,023,548–108,130,361, 1 gene, copy number 5 (within-gene range 2–5): LAMB4.
- chr14:105,785,505–106,473,000, 119 genes, copy number 8 (broad region; genes not listed).
- chr15:25,062,333–25,081,378, 11 genes, copy number 9: SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr19:47,745,546–47,794,920, 6 genes, copy number 7: NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1.

Autosomal genes at a single copy (total copy number 1): 935. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
